Gene-level copy-number profile of tumor specimen ALCH-B0CY-TTP1-A from ALCHEMIST case ALCH-B0CY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 81.5 years (29,774 days).
Specimen ALCH-B0CY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 858cfb25-67e3-405f-add1-1e43513c1f30.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/c410e74b-a2a7-475c-9943-4a03210b04d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 367; copy number 1: 14,331; copy number 2: 40,339; copy number 3: 3,250; copy number 4: 469; copy number 5: 95; copy number 6: 21; copy number 10: 20; copy number 13: 8.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,035,178–16,057,308, 2 genes: AL355994.2, CLCNKB.
- chr2:218,382,029–218,405,941, 4 genes: SLC11A1, CTDSP1, AC021016.2, MIR26B.
- chr3:50,337,511–50,504,244, 10 genes (within-gene range 0–2): RASSF1-AS1, ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115, CACNA2D2, Z84492.1, RNA5SP131.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr7:44,104,345–44,114,562, 2 genes: AEBP1, MIR4649.
- chr10:124,623,353–124,624,079, 1 gene (within-gene range 0–1): AL513190.1.
- chr14:73,237,497–73,274,640, 4 genes (within-gene range 0–2): PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr15:25,159,221–25,211,877, 25 genes (within-gene range 0–2): SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr16:10,691,273–10,719,762, 2 genes (within-gene range 0–2): AC007595.1, MTCYBP33.
- chr17:81,388,126–81,390,319, 1 gene: AC110285.2.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr21:43,322,417–43,366,566, 3 genes: LINC00322, LINC01679, AP001046.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 111 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:115,581,315–115,581,442, 1 gene, copy number 5: SNORA25B.
- chr7:115,789,729–117,230,176, 34 genes, copy number 6–13 (within-gene range 2–13): AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6.
- chr11:69,072,915–69,162,440, 1 gene, copy number 5 (within-gene range 1–5): AP003071.5.
- chr11:69,103,493–70,436,584, 38 genes, copy number 5: AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:18,333,726–18,341,859, 1 gene, copy number 10: CR383658.1.
- chr18:316,737–2,049,510, 36 genes, copy number 5 (within-gene range 3–5): AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1.

Autosomal genes at a single copy (total copy number 1): 12,144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
